Somatic mutation profile of tumor specimen TCGA-EA-A1QS-01A (aliquot TCGA-EA-A1QS-01A-61D-A22X-09) from TCGA case TCGA-EA-A1QS, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 46.3 years (16,923 days).
Specimen TCGA-EA-A1QS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 808999f1-e02c-4303-adb8-3ea1fc971f49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A1QS-10A (Blood Derived Normal), aliquot TCGA-EA-A1QS-10A-01D-A22X-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98c9308b-fa4f-4c52-be90-06d9b1900245

The open-access MAF lists 53 somatic variants for this specimen: 44 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 38, Silent 9, Nonsense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2
- RYR2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs727503396, COSV63664819; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AC006059.2 | c.498G>C p.K166N | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV59607340; called by muse, mutect2, varscan2
- ADAM9 | c.2264G>T p.R755L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV65959869, COSV65960534; called by muse, mutect2
- ARCN1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV50615450; called by muse, mutect2, varscan2
- ATP8B2 | c.3376C>A p.P1126T (on ENST00000672630; = p.P1093T on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63832033; called by muse, mutect2
- C1orf112 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs766486942, COSV99609982; called by mutect2, varscan2
- CBWD2 | c.561C>G p.I187M | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.219); catalogued as COSV99380680; called by muse, mutect2
- DACH2 | c.530C>G p.S177* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV64171594; called by muse, mutect2, varscan2
- DAGLA | c.1822G>A p.V608M | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57196302, COSV99944109; called by muse, mutect2, varscan2
- ERV3-1 | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.97); catalogued as COSV51428098; called by muse, mutect2, varscan2
- FAT1 | c.7349C>G p.S2450* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV71673814, COSV71675311; called by muse, mutect2, varscan2
- FKBP4 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV50009221; called by muse, mutect2, varscan2
- FLNA | c.3550G>C p.D1184H | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100774920; called by muse, mutect2
- GFM1 | c.1642C>T p.Q548* | Nonsense Mutation (SNP) | VAF 4/55 reads (7%) | catalogued as rs1214047183, COSV99962882, COSV99963025; called by muse, mutect2
- IP6K2 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV53661726; called by muse, mutect2, varscan2
- IRAK2 | c.1111A>T p.K371* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99844162; called by muse, mutect2
- KDM1A | c.757C>A p.H253N | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63088396; called by muse, mutect2, varscan2
- LGALS13 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV55679790; called by muse, mutect2
- LRRC43 | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as COSV57336611; called by muse, mutect2, varscan2
- MLLT10 | c.1007G>C p.R336T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.614); catalogued as COSV56997292; called by muse, mutect2, varscan2
- NIP7 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99650838; called by muse, mutect2
- NOD2 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.189); catalogued as COSV56051685; called by muse, mutect2
- NPTN | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99766634; called by muse, mutect2
- NR2F2 | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV67683587; called by muse, mutect2, varscan2
- PACRGL | c.569G>C p.G190A | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54843046; called by muse, mutect2, varscan2
- PPP4R3A | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.604); catalogued as COSV61505003; called by muse, mutect2
- RASGRP4 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as COSV53095883; called by muse, mutect2, varscan2
- RYR2 | c.4449C>A p.S1483R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.677); catalogued as COSV63689937; called by muse, mutect2, varscan2
- SASH1 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.049); catalogued as COSV66562423; called by muse, mutect2, varscan2
- SDR42E1 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV100200749, COSV61095104; called by muse, mutect2
- SETDB1 | c.2955G>C p.L985F | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54989799, COSV99645345; called by muse, mutect2
- SLC29A4 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs202005474, COSV51874212, COSV99786867; called by muse, mutect2
- SLC6A11 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV54394504; called by muse, varscan2
- TNXB | c.7855T>G p.Y2619D (on ENST00000647633; = p.Y2372D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64480450; called by muse, mutect2
- TSNARE1 | c.365A>G p.K122R | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.043); catalogued as COSV100211024; called by muse, mutect2
- TTN | c.25528C>T p.L8510F (on ENST00000591111; = p.L7583F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | PolyPhen probably damaging (0.96); catalogued as COSV60114865; called by mutect2, varscan2
- VCP | c.585A>T p.E195D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as COSV62720870; called by muse, mutect2, varscan2
- ZEB1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753521729, COSV58046007; called by muse, mutect2, varscan2
- ZNF292 | c.2363G>A p.R788K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.063); catalogued as COSV60540621; called by muse, mutect2, varscan2
- ZNF302 | c.1424C>G p.P475R (on ENST00000627982; = p.P396R on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71063633, COSV71063668; called by muse, mutect2, varscan2
- ZNF473 | c.2527C>T p.Q843* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV54523460; called by muse, mutect2, varscan2
- KIAA0319L | c.111C>A p.C37* | Nonsense Mutation (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- SUPT20HL2 | c.121T>C p.Y41H | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2
- ATG9A | c.1854G>C p.L618= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99522034; called by muse, mutect2, varscan2
- CHST8 | c.804C>T p.F268= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV52859609; called by muse, mutect2, varscan2
- HOMER3 | c.438C>T p.A146= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99651178; called by muse, mutect2, varscan2
- PCDHB3 | c.2130G>A p.A710= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as rs531712675, COSV50577138; called by muse, mutect2
- TCFL5 | c.1426C>T p.L476= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV53897011, COSV53897236; called by muse, mutect2, varscan2
- TCP11L1 | c.1266C>T p.T422= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs756467493, COSV57514872; called by mutect2, varscan2
- TSPAN32 | c.249C>T p.T83= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as rs1002836093, COSV99478303; called by muse, mutect2
- ZDHHC9 | c.264C>T p.F88= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV64096038; called by muse, mutect2, varscan2
- ZNF543 | c.363C>G p.S121= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100386880, COSV58627809; called by muse, mutect2
